Somatic mutation profile of tumor specimen 0DPHTP from CCDI case PBCDPB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 14.6 years (5,340 days).
Specimen 0DPHTP: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2526920-6bbb-46a3-8c31-71022883c7d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPHSY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06883fb9-0f50-4ec3-bb55-f420b4d8b04b

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Intron 3, Splice Site 2, Silent 2, Frame Shift Ins 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYOD1 | c.365T>G p.L122R | Missense Mutation (SNP) | VAF 120/325 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51452486; called by muse, mutect2, varscan2
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 206/538 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCDC113 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 247/638 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as rs776075445, COSV54686262, COSV54687170; called by muse, mutect2, varscan2
- CNGA4 | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 185/449 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as COSV66005359; called by muse, mutect2, varscan2
- IPO7 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 193/415 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs376273953; called by muse, mutect2, varscan2
- LAMA3 | c.8491G>A p.D2831N (on ENST00000313654 / NM_198129.4; = p.D1222N on NM_000227.6) | Missense Mutation (SNP) | VAF 109/424 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as rs758227162, COSV52538677; called by muse, mutect2, varscan2
- MAGEB6 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 250/306 reads (82%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs775192724, COSV66872018; called by muse, mutect2, varscan2
- MEGF10 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 87/392 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371078929; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCKAP1L | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 55/369 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769776941; called by muse, mutect2, varscan2
- PHLDB1 | c.2810G>A p.G937D | Missense Mutation (SNP) | VAF 14/550 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs1555121939; called by muse, mutect2
- RHO | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 210/433 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs781237162, COSV56214899; called by muse, mutect2, varscan2
- SALL3 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 111/205 reads (54%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.801); catalogued as rs570117166; called by muse, mutect2, varscan2
- TRIM9 | c.1760G>T p.R587L | Missense Mutation (SNP) | VAF 109/281 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104403756; called by muse, mutect2, varscan2
- VASH1 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 51/184 reads (28%) | catalogued as COSV51337400; called by muse, mutect2, varscan2
- CUL2 | c.194dup p.L65Ffs*10 | Frame Shift Ins (INS) | VAF 76/268 reads (28%) | called by mutect2, varscan2
- EYS | c.5175G>A p.M1725I | Missense Mutation (SNP) | VAF 185/359 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYDIN | c.11517G>T p.W3839C | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- IPO4 | c.2421+1G>T p.X807_splice | Splice Site (SNP) | VAF 89/507 reads (18%) | called by muse, mutect2, varscan2
- KRT9 | c.673A>G p.T225A | Missense Mutation (SNP) | VAF 120/338 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2
- LCE2C | c.59G>T p.C20F | Missense Mutation (SNP) | VAF 304/791 reads (38%) | SIFT tolerated, low confidence (0.84); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- NARS1 | c.946T>G p.C316G | Missense Mutation (SNP) | VAF 179/333 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RCBTB2 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 103/364 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC12A7 | c.3151G>C p.D1051H | Missense Mutation (SNP) | VAF 376/890 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); called by muse, mutect2
- TBL2 | c.261+2T>C p.X87_splice | Splice Site (SNP) | VAF 124/298 reads (42%) | called by muse, mutect2, varscan2
- XPO5 | c.962G>A p.R321K | Missense Mutation (SNP) | VAF 122/506 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ZBTB8B | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 130/295 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- NOD2 | c.957G>A p.G319= | Silent (SNP) | VAF 144/351 reads (41%) | catalogued as rs1300854975; called by muse, mutect2, varscan2
- RGCC | c.159C>T p.Y53= | Silent (SNP) | VAF 109/367 reads (30%) | called by muse, mutect2, varscan2
- CCDC90B | c.594+22T>C | Intron (SNP) | VAF 99/295 reads (34%) | called by muse, mutect2, varscan2
- ITGA5 | c.2307-53C>T | Intron (SNP) | VAF 113/282 reads (40%) | catalogued as rs1226887017; called by muse, mutect2
- SKA3 | c.*109G>A | 3'UTR (SNP) | VAF 38/141 reads (27%) | called by muse, mutect2, varscan2
- THADA | c.2311+95G>T | Intron (SNP) | VAF 38/126 reads (30%) | called by muse, mutect2, varscan2
